Somatic mutation profile of tumor specimen TCGA-KQ-A41N-01A (aliquot TCGA-KQ-A41N-01A-11D-A339-08) from TCGA case TCGA-KQ-A41N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Ureteric orifice; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.5 years (26,837 days).
Specimen TCGA-KQ-A41N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30033e4f-180c-4aea-b18b-e393d58178f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KQ-A41N-10D (Blood Derived Normal), aliquot TCGA-KQ-A41N-10D-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b72c93cc-7332-43d1-ac7e-808866b732cf

The open-access MAF lists 272 somatic variants for this specimen: 210 protein-altering or splice-affecting, 54 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 54, Nonsense Mutation 17, Frame Shift Del 10, Splice Site 6, Frame Shift Ins 5, In Frame Del 3, RNA 2, 5'UTR 2, 5'Flank 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD11 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782231905, COSV99766690; called by muse, mutect2, varscan2
- ACSS1 | c.1452G>C p.K484N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV100053467; called by muse, mutect2, varscan2
- ADAD2 | c.1553_1558del p.L518_K520delinsQ (on ENST00000315906 / NM_001145400.2; = p.L600_K602delinsQ on NM_139174.4) | In Frame Del (DEL) | VAF 37/115 reads (32%) | catalogued as COSV51894337; called by mutect2, pindel, varscan2
- ADAM21 | c.875A>T p.H292L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV50800037; called by muse, mutect2, varscan2
- ADAM29 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 64/134 reads (48%) | catalogued as rs1351698820, COSV100821928; called by muse, mutect2, varscan2
- ADGRA3 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV51565663; called by muse, mutect2, varscan2
- AGTPBP1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61274487, COSV61275948; called by muse, mutect2, varscan2
- AKAP13 | c.479-2A>G p.X160_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV63464462; called by muse, mutect2, varscan2
- ANP32A | c.284T>C p.L95S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51189740; called by muse, mutect2, varscan2
- ANXA2 | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV60317711; called by muse, varscan2
- ARHGAP12 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs369851721; called by mutect2, varscan2
- ARHGEF12 | c.2704C>G p.Q902E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV63106092; called by muse, mutect2, varscan2
- ARID2 | c.2348T>A p.I783N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV57609540; called by muse, mutect2, varscan2
- ASIC2 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV63317809; called by mutect2, varscan2
- ASIC3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1172536516, COSV52507384; called by muse, mutect2, varscan2
- ASNSD1 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV53624285; called by muse, varscan2
- ATM | c.3746+1G>A p.X1249_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | catalogued as CS149508, COSV53758151; called by muse, mutect2, varscan2
- ATP8A1 | c.2666A>T p.E889V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV52540937; called by muse, mutect2, varscan2
- ATRNL1 | c.1442T>C p.I481T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1554896081, COSV61810181; called by muse, mutect2, varscan2
- AXDND1 | c.1610C>G p.S537* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100858271; called by muse, mutect2, varscan2
- B4GALT3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs202068319, COSV60527589; called by muse, mutect2, varscan2
- BRD4 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1266879236, COSV54590095; called by muse, mutect2, varscan2
- C18orf32 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.422); catalogued as rs372217659; called by muse, varscan2
- CACNA1D | c.5863C>A p.Q1955K (on ENST00000350061 / NM_001128840.3; = p.Q1975K on NM_000720.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV55456113; called by muse, mutect2, varscan2
- CCDC14 | c.752C>G p.T251R (on ENST00000488653; = p.T203R on NM_022757.5) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV59946173; called by muse, mutect2, varscan2
- CCDC47 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs200914420, COSV56723862; called by muse, varscan2
- CCIN | c.678T>A p.N226K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV58725121; called by muse, varscan2
- CCNA1 | c.670-2A>G p.X224_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV55222826; called by muse, mutect2, varscan2
- CCNL2 | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV68766888; called by muse, mutect2, varscan2
- CDK6 | c.366A>G p.I122M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56010438; called by muse, mutect2, varscan2
- CELSR3 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543483822, COSV50926464, COSV99374290; called by muse, mutect2, varscan2
- CENPF | c.6670G>A p.G2224S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.042); catalogued as rs375601206; called by muse, varscan2
- CEP192 | c.7129C>T p.H2377Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1256949218, COSV58067429; called by mutect2, varscan2
- CEP55 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV65185463; called by mutect2, varscan2
- CH25H | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV64092442; called by muse, mutect2, varscan2
- CHTF18 | c.2278G>C p.D760H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772926692, COSV99242390; called by muse, varscan2
- CIDEC | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs757906759, COSV100396619, COSV61062187; called by muse, mutect2, varscan2
- CLDN16 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as CM015915, COSV53228629, COSV99290296; called by muse, mutect2, varscan2
- COLGALT1 | c.1205del p.G402Afs*13 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV99394862; called by mutect2, pindel, varscan2
- CPA2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55980578; called by muse, mutect2, varscan2
- CPNE1 | c.801+1G>C p.X267_splice (on ENST00000352393; = p.X272_splice on NM_003915.5) | Splice Site (SNP) | VAF 33/93 reads (35%) | catalogued as COSV58293212; called by muse, mutect2, varscan2
- CPNE9 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99808094; called by muse, mutect2, varscan2
- CS | c.919-1G>C p.X307_splice | Splice Site (SNP) | VAF 36/80 reads (45%) | catalogued as COSV57525404; called by muse, varscan2
- CTR9 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV63729138; called by muse, mutect2, varscan2
- CUL7 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV54819609; called by mutect2, varscan2
- DDX50 | c.659C>A p.T220K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1302001420, COSV65292885; called by muse, mutect2, varscan2
- DIDO1 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.73); catalogued as rs757184367, COSV56624423; called by muse, mutect2, varscan2
- DMD | c.3617A>C p.E1206A | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV63774262; called by muse, mutect2, varscan2
- DNAH7 | c.5455C>G p.L1819V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV56774694; called by muse, mutect2, varscan2
- DNHD1 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV54439931; called by muse, varscan2
- DPP8 | c.594G>A p.T198= (on ENST00000341861 / NM_001320875.2; = p.T182= on NM_017743.6) | Splice Region (SNP) | VAF 38/108 reads (35%) | catalogued as rs776118371, COSV55681039; called by muse, varscan2
- DTX3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.068); catalogued as rs759444551, COSV99677624; called by muse, varscan2
- EIF2AK2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV99240376; called by mutect2, varscan2
- EIF5 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs750274016, COSV53686109, COSV53686346; called by muse, mutect2, varscan2
- ELF3 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 92/184 reads (50%) | catalogued as COSV62841040; called by muse, mutect2, varscan2
- EXO1 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV62218486, COSV62220033; called by muse, mutect2, varscan2
- FABP5 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.154); catalogued as COSV99793013; called by muse, mutect2, varscan2
- FANCD2OS | c.92A>T p.H31L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV67558162; called by muse, mutect2, varscan2
- FBXL14 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1341819604, COSV59336820; called by mutect2, varscan2
- FBXO43 | c.112A>T p.R38W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV71054755; called by muse, mutect2, varscan2
- FCAR | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as COSV62030725; called by muse, mutect2
- FLT3 | c.2537G>A p.G846D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54061369; called by muse, mutect2, varscan2
- FNDC8 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV50102673; called by muse, mutect2, varscan2
- FRMPD2 | c.3586G>T p.D1196Y | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100563590; called by muse, mutect2, varscan2
- GDPD3 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs756311411, COSV100650768; called by muse, mutect2, varscan2
- GIMAP8 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV56232715; called by muse, varscan2
- GJA10 | c.1319A>T p.K440M | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV65355294, COSV65355634; called by muse, mutect2, varscan2
- GLI2 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100082775, COSV58046525; called by muse, mutect2, varscan2
- GPNMB | c.1622T>G p.L541R (on ENST00000381990 / NM_001005340.2; = p.L529R on NM_002510.3) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV51699563; called by muse, mutect2, varscan2
- GPR149 | c.865A>G p.R289G | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV67668572; called by muse, mutect2, varscan2
- GPR162 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50592866; called by muse, mutect2, varscan2
- GPRASP1 | c.3587G>A p.G1196D | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64356085; called by muse, mutect2, varscan2
- H1-0 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV50649462; called by muse, mutect2, varscan2
- HDLBP | c.2666T>C p.M889T | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60498827; called by muse, mutect2, varscan2
- HIP1R | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as COSV53443101; called by muse, mutect2, varscan2
- HMG20A | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100287678; called by mutect2, varscan2
- HSF1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as rs1368680287, COSV60048726; called by mutect2, varscan2
- HSPB9 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV56791853, COSV56793229; called by muse, mutect2, varscan2
- IFT140 | c.2993A>T p.Q998L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV54153833; called by muse, mutect2, varscan2
- IGSF9B | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374101848; called by muse, mutect2, varscan2
- INTS1 | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.122); catalogued as rs759843212, COSV67178508; called by muse, varscan2
- KCNH7 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59804724; called by muse, mutect2
- KCNMB3 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs1475164659, COSV100046474; called by muse, mutect2, varscan2
- KLHL7 | c.1441G>C p.D481H (on ENST00000339077 / NM_001031710.3; = p.D433H on NM_018846.5) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV59162869; called by muse, mutect2, varscan2
- KMT2C | c.4042T>C p.Y1348H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51468995; called by muse, mutect2, varscan2
- KRT10 | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV54089020, COSV54089234; called by muse, varscan2
- LAMB4 | c.1701G>C p.L567F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV52724521; called by muse, mutect2, varscan2
- LDB3 | c.1804T>A p.Y602N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53945740; called by mutect2, varscan2
- LEF1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54469938; called by muse, mutect2, varscan2
- LIPI | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV100753290, COSV60713828; called by muse, mutect2, varscan2
- MAD1L1 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs577277453, COSV56231544; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBD1 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54003967; called by muse, mutect2, varscan2
- MBD6 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV63075556; called by muse, mutect2, varscan2
- MDC1 | c.648G>T p.L216F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV64525697; called by mutect2, varscan2
- METTL14 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV101183372, COSV101183403; called by muse, mutect2, varscan2
- METTL14 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310855; called by muse, varscan2
- METTL14 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310313, COSV66310860; called by muse, varscan2
- MEX3B | c.517G>C p.G173R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61663879; called by muse, varscan2
- MFSD14B | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs1471247880, COSV64701339; called by muse, mutect2, varscan2
- MPZL3 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1011365492, COSV54053640; called by muse, mutect2, varscan2
- MTO1 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV64774347; called by muse, varscan2
- MYBPC2 | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV63097692; called by muse, mutect2, varscan2
- MYPN | c.3125G>T p.R1042L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62735939; called by muse, varscan2
- NAV3 | c.5036C>T p.A1679V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV57096042; called by muse, mutect2, varscan2
- NEDD9 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV65159165; called by muse, mutect2, varscan2
- NELFE | c.435A>T p.E145D | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV64812865; called by muse, mutect2, varscan2
- NIPAL1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55007153; called by muse, mutect2, varscan2
- NSD1 | c.1949A>G p.D650G | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV61779700; called by muse, mutect2, varscan2
- NSD3 | c.690G>C p.R230S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57620602; called by muse, mutect2, varscan2
- NSMCE1 | c.283T>G p.S95A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV63864532; called by muse, mutect2, varscan2
- NUP210 | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV54409669; called by muse, mutect2, varscan2
- OCIAD1 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as rs148329796; called by muse, mutect2, varscan2
- PAQR5 | c.754C>G p.H252D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61818538; called by muse, mutect2, varscan2
- PARD3 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs779702389, COSV60755092; called by muse, varscan2
- PCIF1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100975998; called by muse, mutect2, varscan2
- PGM2L1 | c.563G>T p.W188L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV53348173, COSV53350288; called by mutect2, varscan2
- PHF20 | c.1828G>C p.E610Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV100179936; called by muse, mutect2
- PKHD1 | c.5851G>A p.G1951S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV61886537; called by muse, mutect2, varscan2
- PKN2 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV60133044; called by muse, mutect2, varscan2
- POPDC2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV51739677, COSV51743126; called by muse, mutect2, varscan2
- PPA2 | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100049881, COSV58996949; called by muse, mutect2, varscan2
- PPP4R4 | c.1891A>T p.K631* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100428364, COSV58551774; called by muse, mutect2, varscan2
- PRKDC | c.6133T>A p.F2045I | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58058176; called by muse, varscan2
- PROM1 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV71699667; called by muse, varscan2
- PRPF3 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV61395611; called by muse, mutect2, varscan2
- RAB11FIP4 | c.564-1G>A p.X188_splice | Splice Site (SNP) | VAF 47/144 reads (33%) | catalogued as COSV57931038; called by muse, mutect2, varscan2
- RAB11FIP5 | c.580A>G p.R194G | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV50252989; called by muse, varscan2
- RAB3GAP2 | c.3331A>C p.M1111L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100741073; called by muse, mutect2
- RAB3IP | c.1078G>A p.V360I (on ENST00000550536 / NM_175623.4; = p.V344I on NM_022456.5) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as COSV56085081; called by muse, mutect2, varscan2
- RAD51AP2 | c.3104T>C p.I1035T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1339923998, COSV67588568; called by muse, mutect2, varscan2
- RAG2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV57558655; called by mutect2, varscan2
- RALGPS2 | c.1546A>T p.N516Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV62678941; called by muse, mutect2, varscan2
- REEP5 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.418); catalogued as COSV54843087; called by muse, mutect2, varscan2
- REXO2 | c.322A>C p.K108Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56277355; called by muse, mutect2, varscan2
- REXO5 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54473356; called by muse, mutect2, varscan2
- RHOV | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.584); catalogued as COSV55027797; called by muse, mutect2, varscan2
- RIPPLY3 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV61566911; called by muse, mutect2, varscan2
- RPAP1 | c.3370G>T p.D1124Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV58540900; called by muse, mutect2, varscan2
- RTP5 | c.191A>T p.D64V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV100574679; called by muse, mutect2
- SBNO2 | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1263916109, COSV100684193; called by muse, mutect2, varscan2
- SCNN1B | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs1224634180, COSV56307168; called by muse, mutect2, varscan2
- SESTD1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100090255; called by muse, varscan2
- SHROOM3 | c.1679G>T p.C560F | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56034408; called by muse, mutect2, varscan2
- SLC25A12 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55535058; called by muse, varscan2
- SLC25A42 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100588032; called by muse, mutect2, varscan2
- SLCO4C1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1375030492, COSV60513834, COSV60518009; called by muse, mutect2, varscan2
- SLF2 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs746784502, COSV53276513; called by muse, mutect2, varscan2
- SMARCA2 | c.3413C>T p.A1138V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61809954; called by muse, mutect2, varscan2
- SMCHD1 | c.4429G>C p.E1477Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV55262375; called by muse, mutect2, varscan2
- SMU1 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV68140106; called by muse, mutect2, varscan2
- SNRPB | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60015484; called by muse, mutect2, varscan2
- SORCS1 | c.2677G>A p.V893M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as rs372747201; called by muse, mutect2, varscan2
- SPATA21 | c.297T>A p.H99Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV59187844; called by mutect2, varscan2
- SREBF2 | c.1393del p.D465Mfs*13 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | catalogued as COSV63331882; called by mutect2, pindel, varscan2
- SRSF1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV51964296, COSV51965809; called by muse, mutect2, varscan2
- STING1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV58173071; called by muse, mutect2, varscan2
- STMN4 | c.460G>A p.E154K (on ENST00000265770 / NM_001283054.2; = p.E181K on NM_030795.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV56109564; called by muse, mutect2, varscan2
- STXBP1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV64812445; called by muse, mutect2, varscan2
- SUGP2 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58261867; called by muse, mutect2, varscan2
- SUGP2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58261900; called by muse, mutect2, varscan2
- SVIL | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV63445597; called by muse, mutect2, varscan2
- SYS1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs754380083, COSV54782160; called by muse, mutect2, varscan2
- TACC3 | c.211A>T p.S71C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV57559679; called by muse, mutect2, varscan2
- TAF4 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1238039146, COSV53336184, COSV53340372; called by muse, mutect2, varscan2
- TBC1D1 | c.1370A>G p.E457G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV54723159; called by muse, mutect2, varscan2
- THEG | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV61074353; called by muse, mutect2, varscan2
- TM9SF4 | c.1887C>A p.Y629* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99454080; called by muse, varscan2
- TMC5 | c.679A>G p.S227G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66867453; called by muse, mutect2, varscan2
- TMEM184C | c.696T>A p.Y232* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as COSV99669537; called by muse, varscan2
- TNK1 | c.1571G>A p.R524Q (on ENST00000576812 / NM_001251902.2; = p.R519Q on NM_003985.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs547740599, COSV61171445; called by mutect2, varscan2
- TRANK1 | c.7123G>A p.V2375M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs373549109; called by muse, mutect2, varscan2
- TRPM3 | c.3956T>C p.I1319T (on ENST00000357533 / NM_001366142.2; = p.I1174T on NM_020952.6) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.093); catalogued as COSV62587002; called by muse, mutect2
- TRPM4 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53265902; called by muse, mutect2, varscan2
- TTC3 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV61289827, COSV61293383; called by muse, mutect2, varscan2
- TTN | c.98518C>G p.L32840V (on ENST00000591111; = p.L25416V on NM_003319.4) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | PolyPhen benign (0.006); catalogued as COSV60191439; called by muse, mutect2, varscan2
- UGDH | c.923A>C p.D308A | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV57098960; called by muse, mutect2, varscan2
- UGDH | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV57098970; called by muse, mutect2, varscan2
- UGP2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 76/178 reads (43%) | catalogued as COSV100451531, COSV61427984; called by mutect2, varscan2
- USPL1 | c.795A>G p.I265M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV55000961; called by muse, mutect2, varscan2
- UTY | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV58870922; called by muse, mutect2, varscan2
- VAPA | c.439G>T p.A147S (on ENST00000400000 / NM_194434.3; = p.A192S on NM_003574.6) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61298537; called by muse, mutect2
- WDR44 | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV54165941; called by muse, mutect2, varscan2
- WDR64 | c.2744A>G p.Q915R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.51); catalogued as COSV63797970; called by muse, mutect2, varscan2
- WNT16 | c.719C>G p.S240C (on ENST00000222462 / NM_057168.2; = p.S230C on NM_016087.2) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55976685; called by muse, mutect2, varscan2
- XPO7 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs145466010, COSV53010869; called by muse, mutect2, varscan2
- ZBTB7B | c.1164G>T p.K388N (on ENST00000292176; = p.K422N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52692111, COSV52692260; called by muse, varscan2
- ZFP36L1 | c.812del p.G271Vfs*36 | Frame Shift Del (DEL) | VAF 46/117 reads (39%) | catalogued as rs1421733622; called by mutect2, pindel, varscan2
- ZNF280D | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV50998646; called by muse, mutect2, varscan2
- ZNF430 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV55111297; called by muse, mutect2, varscan2
- ZNF536 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV62828873; called by muse, mutect2, varscan2
- ZNF618 | c.2241C>G p.I747M (on ENST00000374126 / NM_001318042.2; = p.I654M on NM_133374.2) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV55925505, COSV99929799; called by muse, mutect2, varscan2
- ZNF664 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV61878219; called by muse, mutect2, varscan2
- ZRANB2 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV54673028; called by muse, mutect2, varscan2
- ZSWIM4 | c.1803C>G p.I601M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV54319862, COSV99584584; called by muse, mutect2, varscan2
- A4GALT | c.810_826del p.R271Hfs*6 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- C11orf42 | c.717_725del p.S240_P242del | In Frame Del (DEL) | VAF 26/105 reads (25%) | called by mutect2, pindel, varscan2
- CTNND1 | c.1490_1500del p.L497Cfs*13 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, varscan2
- CYB5A | c.279C>A p.N93K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF4 | c.239dup p.L80Ffs*5 | Frame Shift Ins (INS) | VAF 13/24 reads (54%) | called by mutect2, pindel, varscan2
- KDM6A | c.1148_1166del p.S383Nfs*50 | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- LTBR | c.143dup p.E49Gfs*4 | Frame Shift Ins (INS) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- MANBA | c.1952_1954del p.L651del (on ENST00000642252; = p.L605del on NM_005908.4) | In Frame Del (DEL) | VAF 31/95 reads (33%) | called by mutect2, pindel, varscan2
- MMRN2 | c.2772dup p.E925* | Frame Shift Ins (INS) | VAF 67/237 reads (28%) | called by pindel, varscan2
- SPTBN1 | c.3487_3488del p.N1163Sfs*23 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- TBL1XR1 | c.377dup p.N126Kfs*19 | Frame Shift Ins (INS) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- UTP6 | c.744_751del p.F249Cfs*10 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- VCPKMT | c.287_288delinsGTGACTA p.D96Gfs*11 | Frame Shift Ins (INS) | VAF 24/77 reads (31%) | called by pindel, varscan2*
- ZC3H3 | c.113_132del p.G38Afs*7 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | called by pindel, varscan2
- ZFP36L1 | c.410_431del p.F137Sfs*4 | Frame Shift Del (DEL) | VAF 44/174 reads (25%) | called by mutect2, pindel, varscan2
- ACSM2A | c.636C>T p.S212= (on ENST00000219054; = p.S133= on NM_001308169.2) | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99524962; called by muse, mutect2, varscan2
- ADGRF1 | c.1503C>T p.V501= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV51946578; called by muse, mutect2, varscan2
- ALG12 | c.429C>T p.Y143= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV58207836; called by muse, mutect2, varscan2
- ANAPC7 | c.495A>G p.R165= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs139413364; called by muse, mutect2, varscan2
- CDC20B | c.237A>G p.Q79= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV57051504, COSV57054667; called by muse, mutect2, varscan2
- CDH23 | c.8877C>T p.I2959= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs373709237, COSV56460562; called by muse, mutect2, varscan2
- CDH4 | c.2409G>T p.P803= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs138638887, COSV64680583; called by muse, varscan2
- CELSR3 | c.2232G>T p.V744= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV50925924; called by muse, mutect2, varscan2
- CEP126 | c.2379T>A p.A793= | Silent (SNP) | VAF 49/80 reads (61%) | catalogued as COSV54827899; called by muse, mutect2, varscan2
- CFHR5 | c.1698T>C p.P566= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs745639180, COSV56824628; called by muse, mutect2, varscan2
- CP | c.2667C>T p.L889= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52832121; called by muse, varscan2
- CUL9 | c.6438C>G p.L2146= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV52731369; called by muse, mutect2, varscan2
- DDX42 | c.357C>T p.F119= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV63790696; called by muse, varscan2
- EEF1A2 | c.1113G>A p.K371= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV53207153, COSV53208667; called by muse, mutect2, varscan2
- EFTUD2 | c.2616A>G p.K872= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV53656052; called by muse, mutect2, varscan2
- EPS8L1 | c.1596G>A p.L532= (on ENST00000201647 / NM_133180.3; = p.L405= on NM_017729.3) | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV52384139; called by muse, mutect2, varscan2
- HIVEP1 | c.2247G>A p.S749= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs773947058, COSV65103429; called by muse, mutect2, varscan2
- HSPA5 | c.1965G>A p.*655= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99413284; called by muse, mutect2, varscan2
- KLHL9 | c.390C>T p.S130= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV62922170; called by muse, mutect2, varscan2
- LCT | c.2145T>C p.H715= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs559605965, COSV51553517; called by muse, mutect2, varscan2
- LETMD1 | c.705G>C p.L235= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV50398395; called by muse, mutect2, varscan2
- LIPH | c.504T>C p.D168= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs750482764, COSV56184982; called by muse, mutect2, varscan2
- LZTS1 | c.828C>T p.A276= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV56117620; called by muse, mutect2, varscan2
- MAP7D1 | c.762G>A p.S254= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs200195166, COSV60217396; called by muse, mutect2, varscan2
- MTTP | c.936G>A p.R312= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV55507897; called by muse, mutect2, varscan2
- NDST3 | c.1041G>T p.L347= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as COSV56624032; called by muse, mutect2, varscan2
- NES | c.684C>T p.L228= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100957778; called by muse, mutect2
- NRDC | c.174T>C p.S58= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV61406493; called by muse, mutect2, varscan2
- OR13H1 | c.858C>T p.P286= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV58548020; called by muse, mutect2, varscan2
- OR6C74 | c.36T>G p.L12= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV59606818; called by muse, mutect2, varscan2
- PANK3 | c.900C>T p.N300= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV53324190; called by mutect2, varscan2
- PCDH11X | c.3204T>A p.G1068= | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as COSV53486249; called by muse, varscan2
- PCDH12 | c.3537C>T p.S1179= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV51522894; called by muse, mutect2, varscan2
- PDE12 | c.1104C>T p.F368= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV60818187; called by muse, mutect2, varscan2
- PNLIP | c.756T>A p.P252= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV65041278; called by muse, varscan2
- PROM1 | c.906C>G p.L302= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV71699668; called by muse, varscan2
- PTGER4 | c.534G>A p.V178= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1030238785, COSV56721828; called by muse, mutect2, varscan2
- RCBTB2 | c.1161A>G p.E387= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60650898; called by mutect2, varscan2
- RSAD1 | c.804C>T p.G268= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs906977696, COSV51956394; called by muse, mutect2, varscan2
- SHLD2 | c.597G>C p.V199= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100078958; called by muse, mutect2, varscan2
- SLC25A25 | c.369C>G p.L123= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66086601; called by muse, mutect2, varscan2
- SLC8A3 | c.2205G>A p.L735= (on ENST00000381269 / NM_183002.3; = p.L733= on NM_033262.4) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV53691174; called by muse, mutect2, varscan2
- SLFN13 | c.612A>G p.L204= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV53194528; called by muse, mutect2, varscan2
- SPAG17 | c.2577T>C p.D859= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV60463182; called by muse, mutect2, varscan2
- SPO11 | c.94A>C p.R32= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100625649; called by mutect2, varscan2
- TAFA5 | c.384C>A p.T128= (on ENST00000402357 / NM_001082967.3; = p.T121= on NM_015381.7) | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV100385644, COSV60985918; called by muse, mutect2, varscan2
- TFDP2 | c.1089A>G p.L363= (on ENST00000489671 / NM_001178139.2; = p.L303= on NM_006286.5) | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs773731534, COSV57709349; called by muse, varscan2
- TM4SF1 | c.429C>G p.T143= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV59525224; called by muse, mutect2, varscan2
- TPP1 | c.396G>C p.L132= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV54994750; called by mutect2, varscan2
- TTC37 | c.4588T>C p.L1530= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV62455703; called by muse, mutect2, varscan2
- VIPR1 | c.496C>T p.L166= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100285550, COSV57298153; called by muse, mutect2, varscan2
- ZFYVE1 | c.2035C>A p.R679= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV59611930; called by muse, mutect2, varscan2
- ZNF28 | c.906A>G p.E302= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV60424309; called by muse, varscan2
- ZP4 | c.702G>T p.L234= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs1157156513, COSV63912750; called by muse, mutect2, varscan2
- ADGRE4P | n.431T>G | RNA (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ANKIB1 | c.-165G>A | 5'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99728539; called by muse, mutect2
- CDKL1 | c.742-1456T>G | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99367260; called by muse, mutect2, varscan2
- ECPAS | chr9:111484404 G>C | 5'Flank (SNP) | VAF 13/24 reads (54%) | catalogued as COSV52202334; called by muse, mutect2, varscan2
- LINC00518 | n.1051C>T | RNA (SNP) | VAF 108/192 reads (56%) | called by muse, mutect2, varscan2
- LRRC28 | c.-1C>A | 5'UTR (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100113382; called by mutect2, varscan2
- RC3H2 | c.961-180T>G | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100106363; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62855345 G>A | 5'Flank (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
